Gene-level copy-number profile of tumor specimen TCGA-RD-A7BT-01A from TCGA case TCGA-RD-A7BT, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 66.0 years (24,107 days).
Specimen TCGA-RD-A7BT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.9dfb5793-c728-4802-b399-3e94d9a23404.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-RD-A7BT-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f04d12cb-95da-4a2d-bb5a-215b8c83dec1

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 6; copy number 2: 1,028; copy number 3: 16,224; copy number 4: 19,668; copy number 5: 11,318; copy number 6: 5,839; copy number 7: 1,528; copy number 8: 3,014; copy number 9: 846; copy number 10: 183; copy number 11: 3; copy number 12: 55; copy number 16: 32; copy number 21: 1; copy number 23: 2; copy number 24: 4; copy number 25: 3; copy number 26: 9; copy number 77: 3; copy number 85: 1; copy number 86: 9; copy number 87: 1; copy number 90: 4; copy number 91: 3; copy number 92: 14; copy number 118: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-RD-A7BT-01A-11D-A33S-01): tumor purity 0.45, ploidy 4.58, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:100,654,112–101,976,798, 7 genes: AC027315.1, RN7SKP62, ST8SIA4, MIR548P, RN7SL802P, OR7H2P, AC117525.1.
- chr7:111,091,006–111,125,454, 1 gene: LRRN3.
- chr16:78,793,584–78,826,006, 2 genes: AC009141.1, RPS3P7.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,180 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:7,980,146–8,157,788, 5 genes, copy number 9: RNU1-76P, AC116361.1, AC091941.1, AC091912.2, AC091912.1.
- chr7:65,814,672–69,174,450, 70 genes, copy number 9–12 (broad region; genes not listed).
- chr7:69,187,833–69,189,318, 1 gene, copy number 9: AC069280.1.
- chr7:80,245,926–81,335,183, 13 genes, copy number 10: RN7SL869P, AC003988.1, AC004862.1, RN7SL35P, CD36, SNRPBP1, GNAT3, AC073850.1, SEMA3C, AC004972.1, AC005008.2, AC005008.1, AC004866.1.
- chr7:83,955,777–94,834,447, 139 genes, copy number 9–11 (within-gene range 8–11) (broad region; genes not listed).
- chr7:97,598,933–100,272,218, 103 genes, copy number 10 (broad region; genes not listed).
- chr8:125,091,679–127,742,951, 36 genes, copy number 21–90 (within-gene range 5–90): NSMCE2, RN7SL329P, AC084083.1, TRIB1, AC091114.1, AC016074.2, AC016074.1, LINC00861, RNU6-442P, SOD1P3, AC024681.2, KNOP1P5, AC024681.1, RFPL4AP5, AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC.
- chr8:127,795,962–127,796,028, 1 gene, copy number 77: MIR1204.
- chr9:68,328,308–68,531,061, 1 gene, copy number 10 (within-gene range 3–10): PGM5.
- chr9:68,393,881–73,170,393, 66 genes, copy number 10 (broad region; genes not listed).
- chr17:27,798,806–27,894,752, 3 genes, copy number 91 (within-gene range 4–91): AC005697.1, AC005697.2, LYRM9.
- chr17:39,461,486–39,747,291, 14 genes, copy number 92 (within-gene range 3–92): CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7.
- chr17:39,980,807–40,527,002, 32 genes, copy number 16: PSMD3, AC090844.3, CSF3, MED24, MIR6884, SNORD124, THRA, NR1D1, AC068669.1, MSL1, CASC3, MIR6866, RAPGEFL1, MIR6867, WIPF2, CDC6, RARA, AC080112.4, RARA-AS1, AC080112.3, GJD3, AC080112.1, PPIAP54, RNA5SP441, AC080112.2, TOP2A, Y_RNA, RPL23AP75, IGFBP4, AC018629.1, TNS4, AC004585.1.
- chr17:41,712,331–41,823,213, 7 genes, copy number 118: GAST, HAP1, RNA5SP442, RN7SL399P, JUP, P3H4, FKBP10.
- chr20:36,236,459–64,313,132, 689 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
